Gene-level copy-number profile of tumor specimen TCGA-EE-A2M7-06A from TCGA case TCGA-EE-A2M7, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 68.9 years (25,166 days).
Specimen TCGA-EE-A2M7-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.68ecd13c-96dc-4648-9d46-6f30f6f660ba.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A2M7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6dc0054f-2a01-4f5c-8408-646785512532

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 9,618; copy number 3: 19,731; copy number 4: 24,029; copy number 5: 3,803; copy number 6: 354; copy number 7: 2,222; copy number 8: 28; copy number 9: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A2M7-06A-11D-A191-01): tumor purity 0.47, ploidy 3.47, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 30 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:9,614,978–11,832,198, 22 genes, copy number 9 (within-gene range 6–9): GAPDHP68, AC060834.2, PER3P1, AC060834.1, AC006363.1, AC010991.1, AC004936.1, AC004879.1, U3, MGC4859, HSPA8P8, AC009945.1, AC004415.1, Y_RNA, NDUFA4, AC007029.1, PHF14, RPL23AP52, AC004160.1, NPM1P11, THSD7A, AC004160.2.
- chr7:12,211,270–12,243,367, 1 gene, copy number 9: TMEM106B.
- chr7:13,339,201–14,071,380, 6 genes, copy number 9: AC011287.2, AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21.
- chr7:14,190,795–14,192,157, 1 gene, copy number 9: EEF1A1P26.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
